Somatic mutation profile of tumor specimen TCGA-13-0795-01A (aliquot TCGA-13-0795-01A-01W-0371-08) from TCGA case TCGA-13-0795, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 66.8 years (24,403 days).
Specimen TCGA-13-0795-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 82d39fdc-f6c9-4c76-b8a1-74d11b6962a3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-13-0795-10A (Blood Derived Normal), aliquot TCGA-13-0795-10A-01W-0371-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ac5fc05f-256b-432e-a62f-e83b79002126

The open-access MAF lists 86 somatic variants for this specimen: 68 protein-altering or splice-affecting, 18 silent.
By variant classification: Missense Mutation 57, Silent 18, Splice Site 4, Frame Shift Ins 2, Frame Shift Del 2, Nonsense Mutation 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H1-2 | c.67_69del p.K23del | In Frame Del (DEL) | VAF 9/75 reads (12%) | hotspot (GDC flag); catalogued as rs751086925; called by pindel, varscan2
- IFT140 | c.472C>T p.R158W | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.8); catalogued as rs755315693, CM160497, COSV68486119, COSV68488626; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.404G>A p.C135Y | Missense Mutation (SNP) | VAF 33/70 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587781991, COSV52675774, COSV52680475, COSV52702460, COSV53452020; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ADGRV1 | c.10214G>C p.R3405P | Missense Mutation (SNP) | VAF 102/507 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.233); catalogued as COSV67985287, COSV67992259; called by muse, mutect2, varscan2
- ADPRH | c.653A>C p.Q218P | Missense Mutation (SNP) | VAF 30/226 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.343); catalogued as COSV63694999; called by muse, mutect2, varscan2
- AGO1 | c.1328G>T p.G443V | Missense Mutation (SNP) | VAF 23/148 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV64595301; called by muse, mutect2, varscan2
- AHCYL2 | c.448C>T p.Q150* | Nonsense Mutation (SNP) | VAF 57/304 reads (19%) | catalogued as COSV61487223; called by muse, mutect2, varscan2
- APP | c.866A>G p.E289G | Missense Mutation (SNP) | VAF 22/350 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0.403); catalogued as COSV100695945; called by muse, mutect2
- ATP9A | c.551C>T p.S184L | Missense Mutation (SNP) | VAF 18/190 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV58766622; called by muse, mutect2
- CASD1 | c.1329G>C p.L443F | Missense Mutation (SNP) | VAF 18/139 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51972489; called by muse, mutect2, varscan2
- CCDC180 | c.2111T>G p.L704* | Nonsense Mutation (SNP) | VAF 14/50 reads (28%) | catalogued as COSV63830223; called by muse, mutect2, varscan2
- CCR6 | c.28G>A p.D10N | Missense Mutation (SNP) | VAF 69/260 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs1392913906, COSV59474865; called by muse, mutect2, varscan2
- CDH16 | c.1686dup p.K563Qfs*41 | Frame Shift Ins (INS) | VAF 9/86 reads (10%) | catalogued as rs776664434; called by mutect2, pindel, varscan2
- CHGB | c.1407A>T p.R469S | Missense Mutation (SNP) | VAF 33/321 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.334); catalogued as COSV66760501; called by muse, mutect2, varscan2
- CPOX | c.1055G>C p.R352P | Missense Mutation (SNP) | VAF 23/296 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.234); catalogued as COSV51638145, COSV99939135; called by muse, mutect2
- CRNKL1 | c.1658G>A p.R553K | Missense Mutation (SNP) | VAF 24/177 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.125); catalogued as COSV66105904; called by muse, mutect2, varscan2
- DHRS4 | c.140C>T p.A47V | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV57480793; called by muse, mutect2, varscan2
- DNAH1 | c.6972C>A p.D2324E | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.86); catalogued as COSV101326249; called by muse, mutect2, varscan2
- ELMOD3 | c.498C>G p.S166R | Missense Mutation (SNP) | VAF 26/141 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.411); catalogued as COSV59772735; called by muse, mutect2, varscan2
- ENAM | c.2824C>G p.Q942E | Missense Mutation (SNP) | VAF 69/343 reads (20%) | SIFT tolerated (0.6); PolyPhen benign (0.028); catalogued as COSV68535960; called by muse, mutect2, varscan2
- ENOX2 | c.1217-1G>T p.X406_splice (on ENST00000338144 / NM_001382520.1; = p.X377_splice on NM_006375.3 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 22/105 reads (21%) | catalogued as COSV57651736; called by muse, mutect2, varscan2
- FMR1 | c.270+1G>T p.X90_splice | Splice Site (SNP) | VAF 80/391 reads (20%) | catalogued as COSV54423955, COSV99503690; called by muse, mutect2, varscan2
- GLIPR1 | c.482G>T p.G161V | Missense Mutation (SNP) | VAF 18/162 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); catalogued as COSV56990998; called by muse, mutect2, varscan2
- GRIK1 | c.2644A>G p.T882A | Missense Mutation (SNP) | VAF 43/706 reads (6%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0); catalogued as COSV100517175; called by muse, mutect2
- GRM8 | c.1927C>A p.P643T | Missense Mutation (SNP) | VAF 40/382 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58826418; called by muse, mutect2, varscan2
- GUSB | c.1874_1875del p.R625Ifs*7 | Frame Shift Del (DEL) | VAF 120/1071 reads (11%) | catalogued as rs935464108; called by pindel, varscan2
- H4C8 | c.5C>G p.S2C | Missense Mutation (SNP) | VAF 16/133 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.7); catalogued as rs780851749, COSV56804907; called by muse, mutect2, varscan2
- HIVEP1 | c.1081A>T p.S361C | Missense Mutation (SNP) | VAF 40/840 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101045257; called by muse, mutect2
- KLHL10 | c.802G>C p.D268H | Missense Mutation (SNP) | VAF 12/175 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.288); catalogued as COSV53173197; called by muse, mutect2
- LOXL4 | c.2033T>C p.I678T | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs975398697, COSV53256644; called by muse, mutect2, varscan2
- LRRK2 | c.3847T>A p.S1283T | Missense Mutation (SNP) | VAF 29/218 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0.057); catalogued as COSV54153463; called by muse, mutect2, varscan2
- MBD5 | c.2016G>C p.Q672H | Missense Mutation (SNP) | VAF 14/346 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV101290133; called by muse, mutect2
- ME3 | c.130G>A p.V44M | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.071); catalogued as rs200550615, COSV100660998; called by muse, mutect2, varscan2
- MKI67 | c.4964C>T p.T1655I | Missense Mutation (SNP) | VAF 158/950 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.197); catalogued as COSV64074372; called by muse, varscan2
- MUC16 | c.18110G>T p.G6037V | Missense Mutation (SNP) | VAF 23/801 reads (3%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.006); catalogued as COSV101200287; called by muse, mutect2
- MYH3 | c.1702A>G p.K568E | Missense Mutation (SNP) | VAF 60/325 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.525); catalogued as rs1273463426, COSV56865045; called by muse, mutect2, varscan2
- NBPF10 | c.1175G>A p.R392H | Missense Mutation (SNP) | VAF 51/494 reads (10%) | SIFT tolerated (0.52); PolyPhen benign (0.027); catalogued as rs781804321, COSV61671556; called by muse, mutect2, varscan2
- NKAPL | c.569A>G p.K190R | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.028); catalogued as COSV59197962; called by muse, mutect2, varscan2
- PLEKHG2 | c.2816C>T p.P939L | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.996); catalogued as COSV99217642; called by muse, mutect2, varscan2
- PREPL | c.2094+1G>T p.X698_splice | Splice Site (SNP) | VAF 21/186 reads (11%) | catalogued as COSV53216681; called by muse, mutect2, varscan2
- PRKDC | c.8150A>G p.K2717R | Missense Mutation (SNP) | VAF 28/231 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.011); catalogued as COSV58052448; called by muse, mutect2, varscan2
- PTPN5 | c.985A>G p.K329E | Missense Mutation (SNP) | VAF 25/161 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.202); catalogued as COSV62125950; called by muse, mutect2, varscan2
- RAB40AL | c.209C>T p.T70M | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV54434438; called by muse, mutect2, varscan2
- SCAMP2 | c.728G>C p.G243A | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV51511472; called by muse, mutect2, varscan2
- SCGN | c.404G>A p.R135Q | Missense Mutation (SNP) | VAF 96/762 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.018); catalogued as rs200986563, COSV58545554, COSV58547588; called by muse, mutect2, varscan2
- SCN1A | c.4948A>T p.I1650F (on ENST00000303395 / NM_001202435.3; = p.I1639F on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 82/581 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57670317; called by muse, mutect2, varscan2
- SETD6 | c.1055G>A p.G352E (on ENST00000219315 / NM_001160305.4; = p.G328E on NM_024860.3) | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.768); catalogued as COSV50747871; called by muse, mutect2, varscan2
- SLC45A1 | c.1532G>A p.R511H | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs192589202, COSV99239121; called by mutect2, varscan2
- SNW1 | c.580C>G p.Q194E | Missense Mutation (SNP) | VAF 29/150 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.078); catalogued as COSV55054422; called by muse, mutect2, varscan2
- SPIN3 | c.143A>C p.N48T | Missense Mutation (SNP) | VAF 46/231 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.421); catalogued as COSV66529207; called by muse, mutect2, varscan2
- STK38 | c.1062G>T p.K354N | Missense Mutation (SNP) | VAF 36/475 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.71); catalogued as COSV57708906; called by muse, mutect2
- STX3 | c.517A>G p.N173D | Missense Mutation (SNP) | VAF 23/160 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.59); catalogued as COSV55697926; called by muse, mutect2, varscan2
- TTN | c.18949T>G p.Y6317D (on ENST00000591111; = p.Y5390D on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 263/1653 reads (16%) | PolyPhen possibly damaging (0.587); catalogued as COSV60066118; called by muse, mutect2
- TTN | c.18947T>G p.L6316R (on ENST00000591111; = p.L5389R on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 260/1668 reads (16%) | PolyPhen probably damaging (0.988); catalogued as COSV60066129; called by muse, mutect2
- UNC13A | c.3285G>A p.M1095I | Missense Mutation (SNP) | VAF 23/199 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.036); catalogued as COSV53195953; called by muse, mutect2, varscan2
- USP25 | c.2836G>C p.G946R | Missense Mutation (SNP) | VAF 16/135 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.652); catalogued as COSV53484440; called by muse, mutect2, varscan2
- WDR93 | c.946G>A p.G316R | Missense Mutation (SNP) | VAF 103/255 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs142014935; called by muse, mutect2, varscan2
- YBEY | c.273T>G p.I91M | Missense Mutation (SNP) | VAF 24/179 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.578); catalogued as COSV59310049; called by muse, mutect2, varscan2
- ZNF197 | c.1998T>G p.I666M | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.406); catalogued as COSV60360555; called by muse, mutect2, varscan2
- ZNF202 | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.956); catalogued as COSV100279081; called by muse, mutect2
- ZNF451 | c.179A>C p.Y60S | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT tolerated (0.41); PolyPhen benign (0.046); catalogued as COSV100674948; called by muse, mutect2
- ZNF721 | c.2634G>C p.E878D (on ENST00000338977; = p.E890D on NM_133474.4) | Missense Mutation (SNP) | VAF 5/89 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.854); catalogued as COSV100167481; called by muse, mutect2
- ZPLD1 | c.775C>A p.P259T (on ENST00000466937 / NM_001329788.1; = p.P275T on NM_175056.2) | Missense Mutation (SNP) | VAF 119/278 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.524); catalogued as COSV60353557; called by muse, mutect2, varscan2
- BHMT | c.594dup p.G199Rfs*22 | Frame Shift Ins (INS) | VAF 8/59 reads (14%) | called by mutect2, varscan2
- DSEL | c.895_896del p.Q299Vfs*10 | Frame Shift Del (DEL) | VAF 6/63 reads (10%) | called by pindel, varscan2
- LRRC41 | c.2220-14_2220-2del p.X740_splice | Splice Site (DEL) | VAF 4/34 reads (12%) | called by mutect2, pindel
- PIP4K2B | c.469G>T p.V157L | Missense Mutation (SNP) | VAF 58/335 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.547); called by muse, mutect2, varscan2
- TRGC2 | c.394G>A p.D132N | Missense Mutation (SNP) | VAF 26/848 reads (3%) | SIFT tolerated (0.6); PolyPhen benign (0.01); called by muse, mutect2
- AHNAK2 | c.8241G>A p.K2747= | Silent (SNP) | VAF 12/62 reads (19%) | catalogued as rs1205990062, COSV100317972; called by muse, mutect2, varscan2
- BATF2 | c.306G>A p.Q102= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as COSV57249926; called by muse, mutect2, varscan2
- BCL7A | c.489C>T p.N163= | Silent (SNP) | VAF 18/253 reads (7%) | catalogued as COSV99947116; called by muse, mutect2
- BNIP1 | c.27C>T p.V9= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as COSV51570632; called by muse, mutect2, varscan2
- CAT | c.159G>A p.Q53= | Silent (SNP) | VAF 44/372 reads (12%) | catalogued as COSV53811231; called by muse, mutect2, varscan2
- CLASP2 | c.804C>T p.S268= | Silent (SNP) | VAF 26/130 reads (20%) | catalogued as rs760557651, COSV56282560; called by muse, mutect2, varscan2
- GRM8 | c.1665T>A p.L555= | Silent (SNP) | VAF 67/661 reads (10%) | catalogued as COSV58826430; called by muse, mutect2, varscan2
- HELZ | c.2374C>T p.L792= | Silent (SNP) | VAF 10/264 reads (4%) | catalogued as COSV100698833; called by muse, mutect2
- HMOX1 | c.276C>T p.D92= | Silent (SNP) | VAF 7/67 reads (10%) | catalogued as COSV53339839; called by muse, mutect2, varscan2
- KCNT2 | c.2253C>T p.P751= | Silent (SNP) | VAF 11/100 reads (11%) | catalogued as COSV54080117; called by muse, mutect2, varscan2
- LRRFIP2 | c.1170C>T p.D390= | Silent (SNP) | VAF 36/269 reads (13%) | catalogued as rs576073289, COSV60867724; called by muse, mutect2, varscan2
- NR2C1 | c.951C>T p.N317= | Silent (SNP) | VAF 23/117 reads (20%) | catalogued as rs113197444, COSV58009948; called by muse, mutect2, varscan2
- PARP14 | c.4116G>T p.L1372= | Silent (SNP) | VAF 44/115 reads (38%) | catalogued as rs201050912, COSV71734696; called by muse, mutect2, varscan2
- RAB40AL | c.210G>T p.T70= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as rs1175053845, COSV54434457; called by muse, mutect2, varscan2
- RANBP17 | c.1356A>G p.E452= | Silent (SNP) | VAF 81/167 reads (49%) | catalogued as COSV66650288; called by muse, mutect2, varscan2
- SLC51A | c.804A>C p.L268= | Silent (SNP) | VAF 19/187 reads (10%) | catalogued as COSV53057618; called by muse, mutect2
- TUBB4A | c.1101C>T p.F367= | Silent (SNP) | VAF 10/223 reads (4%) | catalogued as rs1422815990, COSV99900037; called by muse, mutect2
- WDR76 | c.51C>T p.P17= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as rs763254055, COSV99776486; called by muse, mutect2, varscan2
